TARGET case TARGET-40-NAAHCY — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c4857bdd-1c27-5095-aa57-2c3ac5a23b04

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 15 years; Vital status: Dead; Days to death: 660 days (1.8 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 15.1 years (5,509 days); Year of diagnosis: 2006; Metastasis at diagnosis: No Metastasis; Days to last follow up: 660 days (1.8 years).
   Treatment given: Protocol identifier: BCM.

Follow-up (2 entries)
- Days to follow up: 238 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 238 days; Days to first event: 238 days; First event: Relapse.
- Days to follow up: 660 days (1.8 years); Year of follow up: 2008.

Biospecimens (3 samples)
- Sample TARGET-40-NAAHCY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAHCY-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAHCY-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 660
- Protocol: BCM
- Disease at diagnosis: Non-metastatic
- Primary tumor site: Leg/foot
- Specific tumor site: Tibia
- Specific tumor region: Proximal
- Definitive Surgery: Amputation
- Site of initial relapse: Lung
- Histologic response: Stage 1/2 (0-90 % necrosis)
- Percent necrosis at Definitive Surgery: 16-33
